Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6941, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6941-01A (Primary Tumor).

DIAGNOSIS

- (A) RIGHT NECK DISSECTION:
Twenty-nine regional lymph nodes, no tumor present.
Submandibular gland, unremarkable.
- (B) "MENTAL HYOID MUSCULAR INSERTION":
Connective tissue; no tumor present.
- (C) RIGHT LINGUAL NERVE:
Peripheral nerve, no tumor present.
- (D) ANTERIOR TONGUE, EXCISION:
Tongue mucosa and underlying connective tissue; no tumor present.
- (E) FLOOR OF MOUTH, TONGUE, LINGUAL CORTEX AND NECK DISSECTION:
INVASIVE GRADE 2 SQUAMOUS CARCINOMA; RESECTION MARGINS FREE OF TUMOR (SEE COMMENT).
Thirty-one regional lymph nodes, no tumor present.
Submandibular gland with chronic sialoadenitis and atrophy; no tumor present.
- (F) "ANTERIOR TONGUE":
Squamous mucosa with mild non-specific chronic inflammation; no tumor present.
- (G) TEETH:
Multiple (two) teeth. (Gross only)
- (H) "ADDITIONAL ANTERIOR TISSUE":
Squamous mucosa; no tumor present.

Entire report and diagnosis completed by: [REDACTED]

Report released by: [REDACTED]

COMMENT

The morphological features of this neoplasm are those of a form of moderately differentiated (grade 2) squamous carcinoma. The bulk of tumor involves the floor of mouth and contiguous tongue. Maximum depth of invasion is 1.8 cm. Peri-neural invasion by tumor is present. No unequivocal lympho-vascular invasion by tumor is identified. Tumor invades minor salivary gland tissue. The final resection margins are free of tumor.

GROSS DESCRIPTION

(A) RIGHT NECK DISSECTION - Multiple lymph nodes, soft tissue and salivary gland (12.0 x 5.0 x 3.0 cm in aggregate). The submandibular gland is identified in level I (5.0 x 3.0 x 1.0 cm). Multiple lymph nodes are identified in all levels ranging from 0.3 to 1.2 cm in greatest dimension. All lymph nodes are submitted in toto.

SECTION CODE:

A1-A4, LEVEL I:

Source: NCI Genomic Data Commons file d4f79419-3295-4783-9770-c74e88a02ff7 (TCGA-CV-6941.90AA16ED-65CF-410C-BB1D-BB8F5B9E468D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).